Somatic mutation profile of tumor specimen TARGET-20-PASSHZ-09A (aliquot TARGET-20-PASSHZ-09A-01D) from TARGET case TARGET-20-PASSHZ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,215 days).
Specimen TARGET-20-PASSHZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab8ecf19-f232-408d-ab13-c0fd4bc0bc53.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASSHZ-14A (Bone Marrow Normal), aliquot TARGET-20-PASSHZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55bdd654-a1f8-4d37-9824-d6900a218edb

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 12/146 reads (8%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 155/177 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NALCN | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315315157, COSV51930283; called by muse, mutect2, varscan2
- ETV6 | c.897_898delinsCCCTTTTT p.R299_E300delinsSPF* | Nonsense Mutation (INS) | VAF 30/81 reads (37%) | called by pindel, varscan2*
